Gene-level copy-number profile of tumor specimen TCGA-CG-5734-01A from TCGA case TCGA-CG-5734, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.7 years (25,079 days).
Specimen TCGA-CG-5734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.583d7ac9-3efa-4f57-a49c-dcd448dd83e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5734-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79119d17-38db-40be-9ff0-4f0ff02ef0a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,392; copy number 2: 48,776; copy number 3: 6,570; copy number 7: 1; copy number 14: 22; copy number 19: 31; copy number 20: 3; copy number 30: 7; copy number 73: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5734-01A-11D-1599-01): tumor purity 0.19, ploidy 1.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,184,461–2,391,707, 7 genes, copy number 30 (within-gene range 2–30): FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr8:14,309,033–14,332,663, 3 genes, copy number 20: EIF4EP5, RNU7-153P, Y_RNA.
- chr8:80,265,907–80,930,081, 22 genes, copy number 14 (within-gene range 2–14): AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1.
- chr15:90,229,975–90,856,207, 32 genes, copy number 7–19: CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P.
- chr18:48,539,031–49,048,474, 11 genes, copy number 73: CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1.
- chr18:49,049,687–49,126,479, 2 genes, copy number 73: MIR4744, AC016866.2.

Autosomal genes at a single copy (total copy number 1): 4,386. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
